CCDI case PBCMSF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/da55bf2e-3055-4823-9ea9-403a65e0218a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 9.8 years (3,569 days).

Biospecimens (3 samples)
- Sample 0DVJNS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVJO4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVJOO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
